TCGA case TCGA-C5-A1MI — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/941f75a1-fea4-4539-ba69-60bb11608f6d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Dead; Days to death: 1,083 days (3.0 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 50.2 years (18,336 days); Year of diagnosis: 2004; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 17; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 118 days; Number of cycles: 6; Prescribed dose: 40; Prescribed dose units: mg/m2/wk; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 125 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 812 days (2.2 years); Route of administration: Intravenous.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 52.4 years (19,141 days); Days to diagnosis: 805 days (2.2 years); Prior treatment: Yes.

Follow-up (15 entries)
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 16 (preoperative): Days to imaging: 16 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 23 (preoperative): Days to imaging: 23 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 41 (prior to adjuvant therapy): ECOG performance status: 1.
- Day 805 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 805 days (2.2 years).
- Days to follow up: 1,083 days (3.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Herpes; Risk factors: Herpes Simplex Virus.
- Timepoint category: Initial Diagnosis; Weight: 77 kg.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Perimenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Ectopic Pregnancy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 35; Age at onset: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-C5-A1MI-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A1MI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1MI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 2; Pregnancies count induced abortion: 2; Pregnancies count ectopic: 1; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 7; Tobacco smoking history indicator: 2; Other immunosuppressive disease: Herpes; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Days to brachytherapy begin occurrence: 83; Brachytherapy total dose point a: 1200; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; Chemo concurrent dose: 40mg/m2/wk; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event type: Distant Metastasis; New tumor event site other: distant recurrence multiple sites; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Therapy regimen: Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,083 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,083 days; disease-free interval: event (new tumor event after initially disease-free), 805 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 805 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1MI-01A-11D-A14V-01): tumor purity 0.67, ploidy 2.75, whole-genome doublings 1.
